Gene-level copy-number profile of tumor specimen TCGA-09-1670-01A from TCGA case TCGA-09-1670, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 57.9 years (21,147 days).
Specimen TCGA-09-1670-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e7b08df1-ec95-4c9e-93a8-b3d5a4b1bc74.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-1670-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/624a9c26-83b7-493a-bb69-7bd6d51f3130

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 742; copy number 2: 23,324; copy number 3: 8,576; copy number 4: 22,462; copy number 5: 4,673; copy number 6: 43.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 739. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
